Somatic mutation profile of tumor specimen ALCH-B0EE-TTP1-A (aliquot ALCH-B0EE-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0EE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 80.2 years (29,298 days).
Specimen ALCH-B0EE-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56a58369-8d71-4117-8e62-12cca7d9659e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0EE-NB1-A (Blood Derived Normal), aliquot ALCH-B0EE-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef8e3b20-cfb0-47b0-8900-64c52140f20d

The open-access MAF lists 185 somatic variants for this specimen: 125 protein-altering or splice-affecting, 38 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 112, Silent 38, Intron 8, Nonsense Mutation 5, 5'UTR 5, Splice Site 3, 3'UTR 3, RNA 3, Splice Region 2, Frame Shift Del 2, 5'Flank 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 29/177 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 107/796 reads (13%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADAC | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 25/390 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs763916912; called by muse, mutect2
- ABCB11 | c.76+1G>A p.X26_splice | Splice Site (SNP) | VAF 14/182 reads (8%) | catalogued as rs1413569310; called by muse, mutect2
- ATAD2B | c.3404G>A p.R1135Q | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.657); catalogued as rs1375708519; called by muse, mutect2
- ATP10A | c.3194C>A p.P1065Q | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV63523412; called by muse, mutect2
- C4orf54 | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 23/374 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.972); catalogued as rs767990966; called by muse, mutect2
- CALM3 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV52194735; called by muse, mutect2
- CDH9 | c.588A>T p.K196N | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99141439; called by muse, mutect2, varscan2
- CECR2 | c.2602G>A p.G868R (on ENST00000342247 / NM_001290047.2; = p.G685R on NM_001290046.1) | Missense Mutation (SNP) | VAF 56/648 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs570964077; called by muse, mutect2
- CUX1 | c.4184C>T p.P1395L | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1318606300; called by muse, mutect2, varscan2
- DOCK6 | c.1213G>A p.V405M | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.657); catalogued as rs777464659; called by muse, mutect2
- DSCAM | c.229C>G p.P77A | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as COSV68656084; called by muse, mutect2
- FBXO34 | c.1573A>T p.S525C | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.518); catalogued as rs774052421, COSV58253997; called by muse, mutect2
- FGFR3 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774929566; called by muse, mutect2, varscan2
- FSCB | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 29/437 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.162); catalogued as rs746081504; called by muse, mutect2
- GPATCH1 | c.136T>G p.Y46D | Missense Mutation (SNP) | VAF 26/386 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs758280196; called by muse, mutect2
- HCN1 | c.2654G>T p.R885L | Missense Mutation (SNP) | VAF 133/1000 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as rs775806199, COSV57498097; called by muse, mutect2, varscan2
- HDAC4 | c.1112A>G p.Q371R | Missense Mutation (SNP) | VAF 50/713 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as COSV61867479; called by muse, mutect2
- HDC | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 30/430 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.195); catalogued as rs754422633, COSV51071662; called by muse, mutect2
- HSD17B7 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 48/646 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs748999552; called by muse, mutect2
- HSF1 | c.120C>T p.S40= | Splice Region (SNP) | VAF 26/200 reads (13%) | catalogued as rs1460662106; called by muse, mutect2, varscan2
- ITGA8 | c.390C>A p.F130L | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65234948; called by muse, mutect2
- LDB2 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.173); catalogued as rs1241862302; called by muse, mutect2
- LOX | c.925G>T p.A309S | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.173); catalogued as COSV50239299; called by muse, mutect2
- MAT1A | c.496G>C p.D166H | Missense Mutation (SNP) | VAF 46/703 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as COSV64747024; called by muse, mutect2
- MUC2 | c.2305G>A p.A769T | Missense Mutation (SNP) | VAF 29/260 reads (11%) | SIFT tolerated (0.24); catalogued as rs528181998; called by muse, mutect2, varscan2
- NAA35 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 12/203 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV64485749; called by muse, mutect2
- NLRC5 | c.4070+1G>A p.X1357_splice | Splice Site (SNP) | VAF 21/202 reads (10%) | catalogued as rs969948546, COSV52649388, COSV52656976; called by muse, mutect2
- NOTCH1 | c.1460G>A p.C487Y | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53057062; called by muse, mutect2, varscan2
- NUTM1 | c.1936C>A p.L646M | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100149163; called by muse, mutect2
- PCSK9 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 34/542 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs376945520; ClinVar: uncertain significance; called by muse, mutect2
- PDLIM1 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 30/470 reads (6%) | catalogued as rs746070320; called by muse, mutect2
- PPP1R12C | c.2239G>T p.A747S | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.95); catalogued as rs768010986, COSV52382046; called by muse, varscan2
- PRDM9 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 54/1135 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as rs755568378, COSV57012182, COSV57015325, COSV99689899; called by muse, mutect2
- PREX1 | c.2267G>A p.G756D | Missense Mutation (SNP) | VAF 18/267 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1384353174, COSV64253438; called by muse, mutect2
- PTCH2 | c.3313G>A p.V1105M | Missense Mutation (SNP) | VAF 36/481 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as rs745450202, COSV100807990, COSV63400321; called by muse, mutect2
- PTGR2 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV50866051; called by muse, mutect2
- RAD54B | c.582G>T p.M194I | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1449351525; called by muse, mutect2
- RHD | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 62/828 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as CM138830; called by muse, mutect2
- RUBCNL | c.1699G>T p.D567Y | Missense Mutation (SNP) | VAF 13/292 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100529107; called by muse, mutect2
- RYR3 | c.192C>G p.C64W | Missense Mutation (SNP) | VAF 14/235 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV66784372; called by muse, mutect2
- SLC18A3 | c.453C>A p.Y151* | Nonsense Mutation (SNP) | VAF 22/321 reads (7%) | catalogued as COSV100340112; called by muse, mutect2
- SLC5A1 | c.1720G>T p.D574Y | Missense Mutation (SNP) | VAF 28/487 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs532222020; called by muse, mutect2
- SLC5A11 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 22/392 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1233398401; called by muse, mutect2
- SPPL2C | c.115T>C p.C39R | Missense Mutation (SNP) | VAF 16/376 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774950031; called by muse, mutect2
- SYNE1 | c.23578G>A p.G7860R (on ENST00000367255 / NM_182961.4; = p.G7789R on NM_033071.3) | Missense Mutation (SNP) | VAF 31/372 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV54927940; called by muse, mutect2
- TBC1D1 | c.1834C>T p.R612W | Missense Mutation (SNP) | VAF 32/473 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs755686916; called by muse, mutect2
- TNNI3K | c.20G>T p.R7I | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV58568836; called by muse, mutect2
- TRPV6 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 33/522 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1466659868; called by muse, mutect2
- TTN | c.53971C>T p.P17991S (on ENST00000591111; = p.P10567S on NM_003319.4) | Missense Mutation (SNP) | VAF 20/376 reads (5%) | PolyPhen benign (0.079); catalogued as COSV60178888; called by muse, mutect2
- UNC5D | c.2722C>G p.R908G | Missense Mutation (SNP) | VAF 17/495 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV54827574, COSV99775090; called by muse, mutect2
- USH2A | c.8212G>T p.D2738Y | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as CM135010, COSV56335912; called by muse, mutect2
- VIM | c.1186G>T p.E396* | Nonsense Mutation (SNP) | VAF 34/483 reads (7%) | catalogued as COSV56404682; called by muse, mutect2
- VXN | c.461T>C p.M154T | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1461670511; called by muse, mutect2
- WDFY4 | c.8049G>C p.E2683D | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV99629326; called by muse, mutect2
- ZFPL1 | c.627C>T p.H209= | Splice Region (SNP) | VAF 14/130 reads (11%) | catalogued as rs148806624; called by muse, mutect2, varscan2
- ABCB5 | c.2107G>T p.G703* (on ENST00000404938 / NM_001163941.2; = p.G258* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2, varscan2
- ABHD17B | c.353T>G p.I118S | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- ADAMTS13 | c.2832G>T p.E944D | Missense Mutation (SNP) | VAF 72/532 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, varscan2
- AHNAK2 | c.9060C>G p.D3020E | Missense Mutation (SNP) | VAF 89/585 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- AMPD1 | c.755C>G p.P252R | Missense Mutation (SNP) | VAF 23/544 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.017); called by muse, mutect2
- ASAH2 | c.1160A>G p.K387R | Missense Mutation (SNP) | VAF 30/487 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.011); called by muse, mutect2
- BTRC | c.1565G>A p.G522E (on ENST00000370187 / NM_033637.4; = p.G486E on NM_003939.5) | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C10orf71 | c.3391G>C p.A1131P | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); called by muse, mutect2
- CIC | c.2878C>T p.P960S | Missense Mutation (SNP) | VAF 37/537 reads (7%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); called by muse, mutect2
- CORIN | c.1144C>G p.Q382E | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.422); called by muse, mutect2
- CROCC2 | c.3682C>A p.H1228N | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CSMD1 | c.7753G>T p.V2585L (on ENST00000520002; = p.V2584L on NM_033225.6) | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (0.78); PolyPhen benign (0.081); called by muse, mutect2
- CYP2S1 | c.1364C>T p.T455I | Missense Mutation (SNP) | VAF 19/617 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- DROSHA | c.292A>T p.I98F | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2
- EIF2AK1 | c.1231+2T>C p.X411_splice | Splice Site (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2, varscan2
- EIF4G1 | c.1585G>C p.D529H (on ENST00000346169 / NM_198241.3; = p.D333H on NM_004953.5) | Missense Mutation (SNP) | VAF 46/660 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2
- EME2 | c.1021C>G p.L341V | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- EPHA10 | c.547C>G p.L183V | Missense Mutation (SNP) | VAF 25/297 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAH | c.843dup p.R282Qfs*9 | Frame Shift Ins (INS) | VAF 61/598 reads (10%) | called by mutect2, pindel, varscan2
- FAM189A1 | c.620T>A p.V207D | Missense Mutation (SNP) | VAF 24/414 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.203); called by muse, mutect2
- FLG2 | c.3079C>A p.Q1027K | Missense Mutation (SNP) | VAF 31/484 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.019); called by muse, mutect2
- GAS2L1 | c.904C>G p.P302A | Missense Mutation (SNP) | VAF 18/253 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.097); called by muse, mutect2
- GPA33 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.179); called by muse, mutect2
- GREB1L | c.3890A>T p.D1297V | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); called by muse, mutect2
- H2BW2 | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.9); called by muse, mutect2
- IPO5 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCNA5 | c.1615C>G p.Q539E | Missense Mutation (SNP) | VAF 32/570 reads (6%) | SIFT tolerated (0.89); PolyPhen benign (0.019); called by muse, mutect2
- KCNJ11 | c.1094_1122del p.R365Hfs*123 | Frame Shift Del (DEL) | VAF 11/115 reads (10%) | called by mutect2, pindel
- KIAA1109 | c.2266G>T p.D756Y | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.018); called by muse, mutect2
- KNTC1 | c.5954A>C p.K1985T | Missense Mutation (SNP) | VAF 22/347 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LEF1 | c.1093G>C p.G365R | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- LINGO1 | c.854A>T p.H285L | Missense Mutation (SNP) | VAF 46/386 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- LOX | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.173); called by muse, mutect2
- LPIN3 | c.237G>T p.K79N | Missense Mutation (SNP) | VAF 24/377 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LRP1B | c.2900G>T p.C967F | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MBOAT1 | c.806A>T p.D269V | Missense Mutation (SNP) | VAF 30/462 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MUC12 | c.1147A>C p.T383P (on ENST00000379442; = p.T240P on NM_001164462.1) | Missense Mutation (SNP) | VAF 33/592 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.846); called by muse, mutect2
- NCF2 | c.1389G>T p.E463D | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.088); called by muse, mutect2
- NES | c.2403T>A p.N801K | Missense Mutation (SNP) | VAF 14/361 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- OR2M3 | c.472A>T p.I158F | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, mutect2
- OR4L1 | c.439C>A p.L147I | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.034); called by muse, mutect2
- OR8A1 | c.74T>A p.L25H | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.107); called by muse, mutect2
- PDE4D | c.787A>G p.I263V (on ENST00000340635 / NM_001104631.2; = p.I127V on NM_006203.4) | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.456); called by muse, mutect2
- PNCK | c.316G>T p.G106C (on ENST00000340888 / NM_001366975.1; = p.G189C on NM_001039582.3) | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PSMD13 | c.556A>C p.K186Q | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.109); called by muse, mutect2
- PTPRB | c.268G>C p.A90P | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RECQL5 | c.2783A>G p.K928R | Missense Mutation (SNP) | VAF 19/376 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.092); called by muse, mutect2
- REG3G | c.505T>A p.Y169N | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RP1L1 | c.1495C>A p.L499M | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.429); called by muse, mutect2
- RPL21 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 38/522 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2
- RTTN | c.5981del p.G1994Dfs*13 | Frame Shift Del (DEL) | VAF 10/104 reads (10%) | called by mutect2, pindel
- RYR2 | c.11096G>A p.C3699Y | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.246); called by muse, mutect2
- SCAND1 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2
- SETBP1 | c.2564C>T p.P855L | Missense Mutation (SNP) | VAF 51/794 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SH3KBP1 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNW1 | c.980T>G p.M327R | Missense Mutation (SNP) | VAF 12/273 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, mutect2
- SPATA5 | c.578T>C p.L193S | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.138); called by muse, mutect2
- STRN4 | c.1442T>G p.V481G | Missense Mutation (SNP) | VAF 16/378 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SULT1A1 | c.105G>T p.Q35H | Missense Mutation (SNP) | VAF 36/572 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- SYTL5 | c.415G>T p.V139F | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TMEM200C | c.1133C>A p.A378D | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2
- TNXB | c.9400G>T p.V3134L (on ENST00000647633; = p.V2887L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/883 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2
- TRIM51GP | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.154); called by muse, mutect2
- TTYH2 | c.653T>A p.L218Q | Missense Mutation (SNP) | VAF 65/416 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- UCHL5 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.122); called by muse, mutect2
- UNC80 | c.4189G>C p.A1397P | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- UQCRFS1 | c.458A>G p.E153G | Missense Mutation (SNP) | VAF 14/363 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- USP6 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 85/680 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ABCA8 | c.1965C>T p.C655= | Silent (SNP) | VAF 22/288 reads (8%) | catalogued as rs781158837, COSV52194068; called by muse, mutect2
- ABHD8 | c.540C>T p.F180= | Silent (SNP) | VAF 22/448 reads (5%) | catalogued as rs1477334134; called by muse, mutect2
- AHNAK | c.16569C>T p.I5523= | Silent (SNP) | VAF 18/242 reads (7%) | catalogued as rs776481511; called by muse, mutect2
- ANKRD13B | c.1137C>G p.P379= | Silent (SNP) | VAF 14/177 reads (8%) | called by muse, mutect2
- BGLAP | c.297G>T p.P99= | Silent (SNP) | VAF 25/217 reads (12%) | catalogued as rs1212343027, COSV52746720; called by muse, mutect2, varscan2
- CARF | c.447C>T p.P149= | Silent (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- CEP135 | c.1335A>C p.T445= | Silent (SNP) | VAF 13/162 reads (8%) | called by muse, mutect2
- CRLF2 | c.228C>A p.L76= | Silent (SNP) | VAF 16/317 reads (5%) | catalogued as COSV67493516; called by muse, mutect2
- CUL4B | c.1824G>A p.K608= | Silent (SNP) | VAF 9/137 reads (7%) | called by muse, mutect2
- ELFN1 | c.669G>T p.P223= | Silent (SNP) | VAF 48/349 reads (14%) | catalogued as COSV70034833; called by muse, mutect2, varscan2
- FAM171B | c.2160C>G p.L720= | Silent (SNP) | VAF 24/267 reads (9%) | catalogued as COSV100489072, COSV59000879; called by muse, mutect2
- FGA | c.291G>A p.K97= | Silent (SNP) | VAF 8/117 reads (7%) | catalogued as COSV100120422; called by muse, mutect2
- FNDC3B | c.1740C>T p.V580= | Silent (SNP) | VAF 26/238 reads (11%) | called by muse, mutect2, varscan2
- GABRA1 | c.169C>T p.L57= | Silent (SNP) | VAF 37/341 reads (11%) | called by muse, mutect2, varscan2
- GEMIN7 | c.285C>A p.T95= | Silent (SNP) | VAF 26/413 reads (6%) | catalogued as rs770245022; called by muse, mutect2
- GPR137 | c.375G>A p.K125= | Silent (SNP) | VAF 16/284 reads (6%) | called by muse, mutect2
- ITGAX | c.2655C>A p.S885= | Silent (SNP) | VAF 20/372 reads (5%) | called by muse, mutect2
- KCNC3 | c.1386C>T p.F462= | Silent (SNP) | VAF 48/692 reads (7%) | catalogued as rs1336436363, COSV100979177; called by muse, mutect2
- KLC2 | c.1674G>A p.E558= | Silent (SNP) | VAF 13/194 reads (7%) | called by muse, mutect2
- KRT33B | c.825G>C p.L275= | Silent (SNP) | VAF 22/454 reads (5%) | called by muse, mutect2
- KY | c.205T>C p.L69= | Silent (SNP) | VAF 26/340 reads (8%) | catalogued as rs1279681937; called by muse, mutect2
- NSG2 | c.225T>A p.L75= | Silent (SNP) | VAF 25/178 reads (14%) | called by muse, mutect2, varscan2
- NT5C1B | c.1416C>A p.L472= (on ENST00000359846 / NM_001199086.2; = p.L412= on NM_033253.4) | Silent (SNP) | VAF 16/258 reads (6%) | catalogued as COSV58395151; called by muse, mutect2
- NUP210L | c.2598G>T p.L866= | Silent (SNP) | VAF 13/306 reads (4%) | called by muse, mutect2
- OVCH1 | c.2770A>C p.R924= | Silent (SNP) | VAF 19/148 reads (13%) | called by muse, mutect2, varscan2
- PANK1 | c.885G>A p.L295= (on ENST00000307534 / NM_148977.2; = p.L70= on NM_138316.4) | Silent (SNP) | VAF 12/239 reads (5%) | called by muse, mutect2
- PTPN11 | c.1029G>A p.R343= | Silent (SNP) | VAF 22/442 reads (5%) | catalogued as COSV100692474, COSV100692827; called by muse, mutect2
- SLC12A7 | c.2913G>T p.P971= | Silent (SNP) | VAF 37/288 reads (13%) | called by muse, mutect2, varscan2
- SORBS2 | c.1335C>T p.N445= | Silent (SNP) | VAF 32/528 reads (6%) | catalogued as rs553201967, COSV53006274; called by muse, mutect2
- SSC5D | c.3000C>T p.T1000= | Silent (SNP) | VAF 20/324 reads (6%) | called by muse, mutect2
- STXBP5L | c.2937T>C p.F979= | Silent (SNP) | VAF 28/450 reads (6%) | called by muse, mutect2
- SYBU | c.591A>G p.S197= (on ENST00000276646 / NM_001099754.2; = p.S196= on NM_017786.6) | Silent (SNP) | VAF 27/411 reads (7%) | called by muse, mutect2
- SYDE1 | c.1125G>C p.L375= | Silent (SNP) | VAF 18/208 reads (9%) | called by muse, mutect2
- TRAV21 | c.171G>A p.Q57= | Silent (SNP) | VAF 25/338 reads (7%) | called by muse, mutect2
- TRPM1 | c.48G>T p.S16= | Silent (SNP) | VAF 24/346 reads (7%) | catalogued as rs773046362; called by muse, mutect2
- UBE4B | c.3216T>A p.R1072= (on ENST00000343090 / NM_001105562.3; = p.R943= on NM_006048.5) | Silent (SNP) | VAF 34/238 reads (14%) | called by muse, mutect2, varscan2
- UPK1A | c.684C>T p.S228= | Silent (SNP) | VAF 22/418 reads (5%) | called by muse, mutect2
- ZNF862 | c.522G>A p.R174= | Silent (SNP) | VAF 36/478 reads (8%) | called by muse, mutect2
- AC004951.2 | n.552G>A | RNA (SNP) | VAF 38/666 reads (6%) | catalogued as rs77510858; called by muse, mutect2
- ACTB | c.123+17G>T | Intron (SNP) | VAF 14/170 reads (8%) | catalogued as rs769849398; called by muse, mutect2
- AIRE | c.-11G>T | 5'UTR (SNP) | VAF 13/188 reads (7%) | called by muse, mutect2
- CD3D | c.56-324C>A | Intron (SNP) | VAF 19/226 reads (8%) | called by muse, mutect2
- CYP21A1P | chr6:32009750 C>G | 3'Flank (SNP) | VAF 72/892 reads (8%) | called by muse, mutect2
- CYP2C9 | c.*27T>A | 3'UTR (SNP) | VAF 18/268 reads (7%) | called by muse, mutect2
- DDR2 | c.1504+30A>T | Intron (SNP) | VAF 18/255 reads (7%) | called by muse, mutect2
- EMC4 | c.201+66C>A | Intron (SNP) | VAF 34/540 reads (6%) | called by muse, mutect2
- ESR1 | c.*18C>A | 3'UTR (SNP) | VAF 14/252 reads (6%) | called by muse, mutect2
- FANCC | c.1329+242G>A | Intron (SNP) | VAF 32/629 reads (5%) | called by muse, mutect2
- HGS | c.468+20A>C | Intron (SNP) | VAF 20/114 reads (18%) | called by muse, mutect2, varscan2
- IQCE | c.1441-1389del | Intron (DEL) | VAF 48/455 reads (11%) | catalogued as COSV58082008; called by mutect2, pindel, varscan2
- KRT18P55 | n.581G>C | RNA (SNP) | VAF 16/150 reads (11%) | called by muse, mutect2, varscan2
- PAPPA | c.*1963C>T | 3'UTR (SNP) | VAF 7/124 reads (6%) | catalogued as rs1009487465; called by muse, mutect2
- RNU6-287P | chr17:42894593 C>G | 5'Flank (SNP) | VAF 10/254 reads (4%) | called by muse, mutect2
- SFTPB | c.393+22C>G | Intron (SNP) | VAF 14/221 reads (6%) | called by muse, mutect2
- SNAI2 | c.-43G>T | 5'UTR (SNP) | VAF 46/531 reads (9%) | called by muse, mutect2
- TMEM104 | c.-49T>A | 5'UTR (SNP) | VAF 33/488 reads (7%) | called by muse, mutect2
- TPGS2 | chr18:36829086 A>T | 5'Flank (SNP) | VAF 17/221 reads (8%) | called by muse, mutect2
- UCK1 | c.-29G>T | 5'UTR (SNP) | VAF 10/34 reads (29%) | catalogued as rs1486020019; called by muse, mutect2, varscan2
- VPS11 | c.-934G>T | 5'UTR (SNP) | VAF 14/420 reads (3%) | called by muse, mutect2
- ZNF812P | n.1004T>C | RNA (SNP) | VAF 12/162 reads (7%) | catalogued as rs1179509642; called by muse, mutect2
